Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3593, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3593-01A (Primary Tumor).

Diagnosis/ diagnoses:

1. Excised soft tissue (abdominal wall) with fibrosis and chronically granulating inflammation. No sections of the rectal carcinoma described in (2) below.
2. Resected part of colon and rectosigmoid colon shows an ulcerated, rectal carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, extending to within 1.3 cm of the aboral resection margin, and encircling the intestinal wall at a length of 6.5 cm, with necrotic tumor lesion. Invasive tumor spread within all intestinal wall layers, deep into the bordering periproctical fatty tissue. The minimum distance from the tumor to the soft tissue resection margin is 2 mm according to microscopy.
Tumor-free oral and aboral resection margin as well as the intestine adherent to the vaginal section and the uterus. Uterus with epidermoid glandular portio ectopy, slightly chronic cervicitis, cystic atrophy of the corpus endometrium and individual intramural leiomyomas. Sigmoid colon wall with individual pseudodiverticula and chronic peridiverticulitis, tending toward scarring.
All 38 periproctical and mesocolic lymph nodes are tumor-free, with non-characteristic reactive lesions.

Tumor stage therefore pT3, pN0, (0/38) L0 V0; G2

Source: NCI Genomic Data Commons file 19e828dc-6d36-40be-a1e3-cadb6320580f (TCGA-AG-3593.85B24198-DC94-497E-989D-4FDF03167EDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).